Surgical pathology report (de-identified scan), TCGA case TCGA-WY-A859, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Johns Hopkins, specimen TCGA-WY-A859-01A (Primary Tumor).

[page 1 of 4]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED]

Accessioned

Birthdate: [REDACTED]

(Age

Loc: [REDACTED]

Gender: F

Spec. Taken

[REDACTED]

=====

INTERPRETATION AND DIAGNOSIS:

1-5) BRAIN: ASTROCYTOMA, GEMISTOCYTIC TYPE, WHO GRADE II, SEE COMMENT.

COMMENT: The tumor has, in some regions, the cellularity and nuclear atypia of a grade III astrocytoma, but mitoses are difficult to find, and the MIB-1 index is within the grade II range.

[REDACTED]

*Electronic signature (

Clinical History:
BRAIN TUMOR

GROSS DESCRIPTION

(Continued on next page.)

chief
ICD-O-3
path Astrocytoma, grade II 9400/3
Astrocytoma, gemistocytic, grade II
9411/3 9400/3
Code to highest 9411/3
Site: *chief* Brain, supratentorial NOS C71.0
path Brain NOS C71.9
WJ 6/10/14

[page 2 of 4]
[REDACTED] Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 2

PART #1: FS: BRAIN TUMOR

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]
Other Pathologists / [REDACTED]

FS: Brain Tumor: Slightly hypercellular brain tissue; rule out low-grade glioma on permanent sections.

Dictated by: [REDACTED]

The specimen for Part 1 is received in saline for frozen section, labeled with the patient's name, [REDACTED] and designated 'Brain Tumor.' The specimen consists of multiple soft white-red fragments of tissue measuring 1.2 x 0.5 x 0.3 cm in aggregate dimension. Touch preps are performed and the specimen is entirely submitted.

SUMMARY OF SECTIONS:

1 - FSC - 3 (FROZEN SECTION CONTROL, BRAIN TUMOR)
1 - TOTAL - 3

(Continued on next page.)

[page 3 of 4]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 3

=====

PART #2: FS: BRAIN TUMOR

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]
Other Pathologists / [REDACTED]

FS: Brain Tumor: Low-grade glioma.

Dictated by: [REDACTED].

The specimen for Part 2 is received in saline for frozen section, labeled with the patient's name, [REDACTED] and designated 'Brain Tumor.' The specimen consists of one (1) soft pale tan-red nodule of tissue measuring 3.2 x 2.2 x 1.5 cm in dimension. Touch preps are performed and representative sections are submitted.

SUMMARY OF SECTIONS:

1 - FSC - M (FROZEN SECTION CONTROL, BRAIN TUMOR)
1 - A - 2
2 - TOTAL - MULTIPLE

PART #3: TUMOR LOCATION "A"

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED] (Parts 3-5).

The specimen for Part 3 is received in saline, labeled with the patient's name, [REDACTED] and designated 'Tumor Location A.' The specimen consists of multiple soft white-red fragments of tissue measuring 1.6 x 0.9 x 0.3 cm in aggregate dimension. The specimen is entirely submitted.

SUMMARY OF SECTIONS:

1 - A - M (BRAIN TUMOR)
1 - TOTAL - MULTIPLE

(Continued on next page.)

[page 4 of 4]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 4

PART #4: TUMOR LOCATION "B"

Resident Pathologist: [REDACTED]

The specimen for Part 4 is received in saline, labeled with the patient's name, [REDACTED], and designated 'Tumor Location B.' The specimen consists of multiple soft white-red fragments of tissue measuring 2.0 x 1.3 x 0.3 cm in aggregate dimension. The specimen is entirely submitted.

SUMMARY OF SECTIONS:

1 - A - M (BRAIN TUMOR)
1 - TOTAL - MULTIPLE

PART #5: BRAIN TUMOR

Resident Pathologist: [REDACTED]

The specimen for Part 5 is received in saline, labeled with the patient's name, [REDACTED] and designated 'Brain Tumor.' The specimen consists of multiple soft white-red-pale tan nodules of tissue measuring 6.0 x 6.0 x 2.1 cm in aggregate dimension. All three (3) cassettes of Part 5 are fixed in 20% formalin overnight. Representative sections are submitted.

SUMMARY OF SECTIONS:

3 - A-C - 3 EA (BRAIN TUMOR)
3 - TOTAL - 9

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Diagnostic Discrepancy		✓
Major Malignancy History		✓

Source: NCI Genomic Data Commons file 851f6dea-b5e5-483b-9db9-78c8885adb7e (TCGA-WY-A859.5A76E8B6-51E3-4E31-9445-DE80E5D47401.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).